FM case AD9307 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Mixed and Stromal Neoplasms; Primary site: Other and unspecified major salivary glands.
https://portal.gdc.cancer.gov/cases/46dc31d0-262b-4dbb-88d5-8817c66a0c23

Male, 51.5 years: Myoepithelial carcinoma (ICD-O-3 8982/3) of the major salivary gland; specimen biopsied or resected from the trachea. Tumor nuclei on the sequenced sample's slide: 80% (pathologist estimate recorded by GDC). Sample type: Tumor.
